Somatic mutation profile of tumor specimen TCGA-AB-2950-03A (aliquot TCGA-AB-2950-03A-01W-0733-08) from TCGA case TCGA-AB-2950, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 34.8 years (12,693 days).
Specimen TCGA-AB-2950-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87401b71-79aa-48c2-b22a-66aff62a78d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2950-11A (Solid Tissue Normal), aliquot TCGA-AB-2950-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86c5bba5-5690-451f-80ed-0ada6d5a3356

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Frame Shift Ins 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99313759; called by muse, mutect2
- KBTBD3 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV101595660; called by muse, mutect2
- KIF3A | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66415351; called by muse, mutect2
- L3MBTL4 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 15/404 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV53128122, COSV99527156; called by muse, mutect2
- MANBA | c.2633T>C p.V878A (on ENST00000642252; = p.V832A on NM_005908.4) | Missense Mutation (SNP) | VAF 7/240 reads (3%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs1379173894, COSV99898234; called by muse, mutect2
- SERTAD4 | c.1007T>C p.L336S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV100882580; called by muse, mutect2
- UHRF2 | c.719A>T p.N240I | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV99436058; called by muse, mutect2
- ZNF133 | c.797G>A p.G266E (on ENST00000316358 / NM_001352454.2; = p.G265E on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/113 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV100315250; called by muse, mutect2
- ELF4 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); called by muse, mutect2
- MTA1 | c.336dup p.Q113Afs*52 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- SIK2 | c.2404C>A p.L802M | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ADNP2 | c.612T>A p.V204= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV100080486; called by muse, mutect2
- AKAP6 | c.399G>T p.L133= | Silent (SNP) | VAF 21/404 reads (5%) | catalogued as rs184880734, COSV99797852; called by muse, mutect2
- LOXL3 | c.1314G>T p.G438= | Silent (SNP) | VAF 10/200 reads (5%) | catalogued as COSV99239397; called by muse, mutect2
- NCKAP5L | c.3777G>A p.L1259= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV100258249, COSV60131712; called by muse, mutect2
- RGS3 | c.1764A>G p.T588= (on ENST00000350696 / NM_001282923.2; = p.T476= on NM_017790.4) | Silent (SNP) | VAF 14/342 reads (4%) | catalogued as COSV100464445; called by muse, mutect2
- SCN5A | c.3066C>T p.T1022= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100346233; called by muse, mutect2
- SLC24A2 | c.285G>T p.L95= | Silent (SNP) | VAF 8/200 reads (4%) | catalogued as COSV99645660; called by muse, mutect2
- ATP2B3 | c.3342+4625T>C | Intron (SNP) | VAF 8/130 reads (6%) | catalogued as COSV54846783; called by muse, mutect2
- TEX2 | c.-2C>T | 5'UTR (SNP) | VAF 7/126 reads (6%) | catalogued as COSV99366721; called by muse, mutect2
